Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3445, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3445-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Mass

Source of Specimen(s):

Left kidney

Gross Description:

Received in one part.

Source of Tissue: 1. Labeled # 1, "left kidney"

Gross Description: Received fresh in a container labeled ", left kidney". It consists of a left radical nephrectomy specimen weighing 638 grams and consists of a left kidney measuring 11.0 x 7.5 x 7.0 cm with some attached perinephric fat measuring from 1.4 up to 4.0 cm from point of attachment. Superior-medially there is some residual adrenal gland measuring only 1.5 x 0.7 x 0.7 cm and is unremarkable. The renal pelvis is a 7.0 cm segment of ureter measuring 0.6 cm in diameter with a pin point lumen. The ureter is opened and is free of lesions or masses. At the hilum the vessels are unremarkable. Dissection through the fat discloses no lesions, masses or nodal tissue. The kidney is bivalved disclosing a central tumor measuring 5.5 x 3.9 x 4.0 cm. The tumor is pushing on the renal pelvis however no lesion is noted. The tumor also pushes on the capsule however no gross invasion is identified in the capsule or fat. The tumor is firm to soft, predominantly orangish-yellow with some more white fibrotic areas and an appreciable amount of hemorrhage. The adjacent parenchyma is brownish-red with no additional lesions or masses and well-defined cortical-medullary junctions. Representative sections are submitted in 1A-J.

Designation of Sections: 1A- vessels and ureter margin, 1B-1C- tumor in relationship to capsule and fat, 1D- tumor in relationship to renal pelvis, 1E- tumor in relationship to adjacent parenchyma, 1F- tumor, 1G- additional overlying fat, 1H- uninvolved kidney, 1I- adrenal gland, 1J- perinephric fat at hilum

Final Diagnosis:

1. Left kidney, radical nephrectomy:
- Clear cell renal cell carcinoma (5.5 cm). Fuhrman nuclear grade III. Tumor invades into perinephric fat. See note.
- Vascular invasion is not identified.
- Renal vein, ureteral and perinephric fat (circumferential) margins are free of tumor.
- Benign adrenal gland.

Note: Tumor cells are positive for CD10, Pancytokeratin and Vimentin and are negative for CD117 supporting the diagnosis.

pT3 Nx Mx.

Source: NCI Genomic Data Commons file 20f32eca-1fd8-4fb6-94ae-0a831ecc645c (TCGA-AK-3445.CBF13E50-41B8-4877-AD8C-D480CDD5077A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).